TCGA case TCGA-BS-A0T9 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of Hawaii. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4eb95566-0e73-4260-853e-f7df650667a0

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 1,428 days (3.9 years).

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 39.0 years (14,253 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IVB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 1; Lymph nodes tested: 2.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 67.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 2; Lymph nodes tested: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 166 days; Number of cycles: 8; Treatment dose: 400 mg/m2; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 166 days; Number of cycles: 8; Treatment dose: 360 mg/m2; Prescribed dose: 45; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 166 days; Number of cycles: 8; Treatment dose: 1,280 mg/m2; Prescribed dose: 160; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Fulvestrant; Initial disease status: Recurrent Disease; Days to treatment start: 950 days (2.6 years); Days to treatment end: 979 days (2.7 years); Number of cycles: 2; Treatment dose: 500 mg; Prescribed dose: 250; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 1,013 days (2.8 years); Days to treatment end: 1,055 days (2.9 years); Treatment dose: 5,600 cGy; Course number: 2; Number of fractions: 28; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,072 days (2.9 years); Days to treatment end: 1,243 days (3.4 years); Number of cycles: 9; Treatment dose: 200 mg/m2; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,072 days (2.9 years); Days to treatment end: 1,243 days (3.4 years); Number of cycles: 4; Treatment dose: 8,000 mg/m2; Prescribed dose: 2000; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,156 days (3.2 years); Days to treatment end: 1,243 days (3.4 years); Number of cycles: 6; Treatment dose: 300 mg/m2; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,163 days (3.2 years); Days to treatment end: 1,250 days (3.4 years); Number of cycles: 9; Treatment dose: 9,000 mg/m2; Prescribed dose: 1000; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,309 days (3.6 years); Days to treatment end: 1,379 days (3.8 years); Number of cycles: 8; Treatment dose: 120 mg/kg; Prescribed dose: 15; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,309 days (3.6 years); Days to treatment end: 1,379 days (3.8 years); Number of cycles: 8; Treatment dose: 1,336 mg; Prescribed dose: 167; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,309 days (3.6 years); Days to treatment end: 1,379 days (3.8 years); Number of cycles: 8; Treatment dose: 640 mg/m2; Prescribed dose: 80; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 40.8 years (14,887 days); Days to diagnosis: 634 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Surgery, NOS; Residual disease: R2.

Follow-up (3 entries)
- Day 634 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 634 days (1.7 years).
- Days to follow up: 1,428 days (3.9 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Premenopausal; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 109 kg; Height: 165 cm; BMI: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BS-A0T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 600 mg.
  Slide TCGA-BS-A0T9-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 30.
  Slide TCGA-BS-A0T9-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 20.
- Sample TCGA-BS-A0T9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BS-A0T9-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Tumor resection; Surgical approach at diagnosis: open; Lymph nodes pelvic pos by he: 0; Lymph nodes pelvic pos by IHC: 0; Lymph nodes aortic pos by he: 0; Lymph nodes aortic pos by IHC: 0.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 0; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event surgery: Yes; New tumor event surgery days to met: 922; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 2; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IM.
- Drug treatment 2: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 5; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 5; Pharmaceutical therapy drug name: taxol; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 1; Pharmaceutical therapy drug name: adriamycin.
- Drug treatment 6: Regimen number: 4; Pharmaceutical therapy drug name: gemzar; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 1; Pharmaceutical therapy drug name: taxol.
- Drug treatment 10: Regimen number: 5; Pharmaceutical therapy drug name: avastin; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,428 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,428 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 634 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BS-A0T9-01A-11D-A12G-01): tumor purity 0.48, ploidy 2.1, whole-genome doublings 0.
